Somatic mutation profile of tumor specimen TCGA-D8-A1XZ-01A (aliquot TCGA-D8-A1XZ-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 81.9 years (29,916 days).
Specimen TCGA-D8-A1XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0755a79-23c5-4e10-ae2b-d01f20a5cc8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XZ-10A (Blood Derived Normal), aliquot TCGA-D8-A1XZ-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15a5fd7a-4706-4853-b166-47c6286b9271

The open-access MAF lists 81 somatic variants for this specimen: 64 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Nonsense Mutation 5, Splice Site 2, In Frame Del 1, RNA 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 17/23 reads (74%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.3577C>G p.Q1193E | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV99282909; called by muse, mutect2
- ADCY4 | c.2772C>G p.I924M | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60257852, COSV60258355; called by muse, mutect2, varscan2
- ADCY5 | c.2183G>A p.S728N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59205820; called by muse, mutect2, varscan2
- AMPH | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1341123866, COSV57760739; called by muse, mutect2, varscan2
- ATP8B4 | c.3428C>T p.T1143I | Missense Mutation (SNP) | VAF 23/861 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99466290; called by muse, mutect2
- AVPR2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs782715616, COSV61686551; called by muse, mutect2, varscan2
- CC2D1A | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58786823; called by muse, mutect2, varscan2
- CDH20 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1296029179, COSV53019897; called by muse, mutect2, varscan2
- CDH9 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346865409, COSV50303173, COSV50488057; called by muse, mutect2, varscan2
- CHST7 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.747); catalogued as COSV99333040; called by muse, mutect2
- CIT | c.505C>A p.H169N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55886691, COSV99948459; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN1 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs547467864, COSV61638757, COSV61642076; called by muse, mutect2
- CRB1 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.245); catalogued as CM060946, COSV66350233; called by muse, mutect2, varscan2
- DCDC1 | c.4126G>T p.A1376S (on ENST00000597505 / NM_001367979.1; = p.A483S on NM_020869.3) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV58004411; called by muse, mutect2, varscan2
- DIAPH3 | c.3187G>A p.D1063N (on ENST00000400324 / NM_001042517.2; = p.D800N on NM_030932.3) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295829065, COSV57383501; called by muse, mutect2, varscan2
- EP300 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV54347631; called by muse, mutect2, varscan2
- FAM13A | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765968303, COSV52013528; called by muse, mutect2, varscan2
- FAM217B | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100674585, COSV62564121; called by muse, mutect2, varscan2
- FAM83G | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1205334812, COSV58763146; called by muse, mutect2, varscan2
- GCNA | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65462430; called by muse, mutect2, varscan2
- GJB3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs147106166; ClinVar: benign; called by muse, mutect2
- GOLM1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763578163, COSV57416304; called by muse, mutect2, varscan2
- GRIN2B | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74208424; called by muse, mutect2, varscan2
- HIPK3 | c.2017C>G p.Q673E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs374207916; called by muse, mutect2, varscan2
- HSPA1L | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV65151413; called by muse, mutect2, varscan2
- HSPH1 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60714342; called by muse, mutect2, varscan2
- ITGAX | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as rs762377072, COSV51643859; called by muse, mutect2, varscan2
- ITGB3BP | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99371194; called by muse, mutect2
- KCNB1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65571493; called by muse, mutect2, varscan2
- LCA5 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 37/197 reads (19%) | catalogued as COSV100878302, COSV63973478; called by muse, mutect2, varscan2
- LRP1B | c.12443T>C p.V4148A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as rs1166966580, COSV67285624; called by muse, mutect2, varscan2
- LRRK2 | c.5455G>C p.G1819R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100110679; called by muse, mutect2
- LUM | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267603717, COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- MAPK4 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1426858848, COSV68541209; called by muse, mutect2, varscan2
- MARK1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65072309; called by muse, mutect2, varscan2
- ONECUT3 | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66639684; called by muse, mutect2, varscan2
- OR10A2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100225088; called by muse, mutect2
- OR2G6 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs373436860; called by muse, mutect2, varscan2
- OR5L1 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100450105, COSV61733980, COSV61735828; called by muse, mutect2
- PHF20 | c.1998G>T p.M666I | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100180455; called by muse, mutect2
- PREX2 | c.3041T>A p.L1014Q | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55775479, COSV99908266; called by muse, mutect2, varscan2
- RADX | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65320376; called by muse, mutect2, varscan2
- RBM12 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1348604854, COSV58295879; called by muse, mutect2, varscan2
- RCAN3 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 48/95 reads (51%) | catalogued as COSV65559138; called by muse, mutect2, varscan2
- RHO | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs781237162, COSV56214899; called by muse, mutect2, varscan2
- RIN3 | c.1201A>T p.S401C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.693); catalogued as COSV99379527; called by muse, mutect2
- SDC2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.207); catalogued as rs200028820; called by muse, mutect2, varscan2
- ST3GAL3 | c.478G>C p.E160Q (on ENST00000361392 / NM_174964.4; = p.E145Q on NM_006279.5) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as COSV53522012; called by muse, mutect2, varscan2
- STAT4 | c.1571-1G>C p.X524_splice | Splice Site (SNP) | VAF 9/144 reads (6%) | catalogued as COSV100636094; called by muse, mutect2
- SUGP1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.118); catalogued as rs1394494957, COSV55924636; called by muse, mutect2, varscan2
- TBX22 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64788256; called by muse, mutect2, varscan2
- THSD7B | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as rs769920310, COSV55747819; called by muse, mutect2, varscan2
- TMCO3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as rs755051458, COSV64808484; called by muse, mutect2, varscan2
- TRPC6 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as COSV60262391; called by muse, mutect2, varscan2
- TTN | c.37634C>A p.T12545K (on ENST00000591111; = p.T5121K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | PolyPhen probably damaging (0.997); catalogued as rs369771893; called by muse, mutect2
- TUBB6 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); catalogued as rs763504507, COSV52312739; called by muse, mutect2, varscan2
- VAV3 | c.175_177del p.E59del | In Frame Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs771926028; called by mutect2, varscan2
- ZBTB2 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57314519; called by muse, mutect2, varscan2
- ZEB1 | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs771873166, COSV58057251; called by muse, mutect2, varscan2
- ZNF423 | c.3334G>A p.V1112M (on ENST00000563137 / NM_001379286.1; = p.V1104M on NM_015069.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV52207326; called by muse, mutect2, varscan2
- AKAP11 | c.206_216+8del p.X69_splice | Splice Site (DEL) | VAF 28/194 reads (14%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CCDC60 | c.618G>A p.Q206= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs773772906, COSV59552429; called by muse, mutect2, varscan2
- ICMT | c.471C>G p.T157= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100658254, COSV100658306; called by muse, mutect2
- IRX1 | c.1434G>A p.P478= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV57360112; called by muse, mutect2
- LRRC1 | c.1209C>T p.D403= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV63831203; called by muse, mutect2, varscan2
- NHS | c.1986G>C p.V662= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV66284790; called by muse, mutect2, varscan2
- NPHP4 | c.3363G>C p.L1121= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65398793; called by muse, mutect2, varscan2
- PCSK7 | c.744C>T p.G248= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs138324399; called by muse, mutect2, varscan2
- PTPN21 | c.897G>A p.A299= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs762919464, COSV60849688; called by muse, mutect2, varscan2
- SCMH1 | c.1425C>G p.L475= (on ENST00000326197 / NM_001031694.2; = p.L428= on NM_012236.4) | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs1392528771, COSV58240936; called by muse, mutect2, varscan2
- SF3A1 | c.1854G>A p.P618= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs774519141, COSV53167850; called by muse, mutect2, varscan2
- SLITRK2 | c.2457C>T p.H819= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100157931; called by muse, mutect2
- ST6GAL2 | c.705G>A p.G235= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100868088; called by muse, mutect2
- TRPM1 | c.1803C>T p.D601= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs569549766, COSV56639201; called by muse, mutect2, varscan2
- TTN | c.17694C>T p.D5898= (on ENST00000591111; = p.D4971= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs372400829; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP9X | c.1803C>T p.D601= | Silent (SNP) | VAF 56/282 reads (20%) | catalogued as COSV61076805; called by muse, mutect2, varscan2
- FAM104B | c.*1_*2del | 3'UTR (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- TUBB7P | n.585C>T | RNA (SNP) | VAF 29/47 reads (62%) | catalogued as rs782193661; called by muse, mutect2, varscan2
